Gene-level copy-number profile of tumor specimen MP2PRT-PAPDYH-TMP1-A from MP2PRT case MP2PRT-PAPDYH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,610 days).
Specimen MP2PRT-PAPDYH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file df20de80-8471-4727-b055-a8e6a4b23a33.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPDYH-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,734 have no estimate.
https://portal.gdc.cancer.gov/files/b232ef74-37f2-4b34-a418-640bce29f8f8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,465; copy number 2: 47,550; copy number 3: 9,794; copy number 4: 55; copy number 5: 25.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 25 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:8,482,270–8,516,759, 1 gene, copy number 5 (within-gene range 3–5): AC105345.1.
- chr14:104,138,723–104,378,951, 3 genes, copy number 5: KIF26A, LINC02691, AL512357.1.
- chr14:104,474,678–104,605,647, 3 genes, copy number 5: TMEM179, C14orf180, BX927359.1.
- chr14:104,830,838–104,978,374, 8 genes, copy number 5: RPS26P49, RPS2P4, AL583810.2, AL583810.1, CEP170B, AL583810.3, PLD4, AHNAK2.
- chr14:105,583,731–105,626,066, 4 genes, copy number 5: IGHA2, IGHE, IGHG4, MIR8071-1.
- chr16:1,078,781–1,113,399, 4 genes, copy number 5: SSTR5, C1QTNF8, AL031713.1, AL031598.1.
- chr21:46,093,264–46,132,848, 2 genes, copy number 5: AP001471.1, COL6A2.

Autosomal genes at a single copy (total copy number 1): 1,465. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
